Somatic mutation profile of tumor specimen ALCH-B4BM-TTP1-A (aliquot ALCH-B4BM-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B4BM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,027 days).
Specimen ALCH-B4BM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7332f63-da89-4c4c-97c9-e639339e63d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4BM-NB1-A (Blood Derived Normal), aliquot ALCH-B4BM-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a78e0c61-81f7-4b85-a18a-d55e3db4c55b

The open-access MAF lists 81 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Intron 8, Frame Shift Del 3, 3'UTR 2, Nonsense Mutation 1, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 196/851 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARX | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as CM024088; called by mutect2, varscan2
- ASH1L | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 21/329 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as COSV64206269; called by muse, mutect2
- BRWD3 | c.2359C>A p.R787S | Missense Mutation (SNP) | VAF 44/430 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV64754297; called by muse, mutect2
- CDK12 | c.2855G>A p.C952Y | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000934, COSV71002420; called by muse, mutect2, varscan2
- CEP112 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV67138725; called by muse, mutect2, varscan2
- CREG2 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs145267496, COSV61318031; called by muse, mutect2
- F8 | c.6319G>A p.G2107S | Missense Mutation (SNP) | VAF 29/605 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267586059, CM980714; called by muse, mutect2
- FAM47B | c.727C>A p.R243S | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as rs1388590471, COSV61454014; called by muse, mutect2
- FAR1 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.053); catalogued as rs1169997159, COSV100701614; called by muse, mutect2, varscan2
- FURIN | c.1115C>G p.P372R | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184753; called by muse, mutect2
- OR13A1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs763151273; called by muse, mutect2
- POTEC | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs1472463592; called by muse, mutect2
- RASAL2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 18/580 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100862225; called by muse, mutect2
- SERPINB3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 76/656 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs369785789, COSV52190624; called by muse, mutect2, varscan2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs760883618; called by pindel, varscan2
- THSD7B | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV55735231, COSV99758170; called by muse, mutect2, varscan2
- WDR87 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs1400950754; called by muse, mutect2, varscan2
- ZMIZ1 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as rs12767060, COSV57903916; called by muse, mutect2
- ZNF622 | c.991T>G p.C331G | Missense Mutation (SNP) | VAF 69/493 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1290863229; called by muse, mutect2, varscan2
- ADAM23 | c.1619G>T p.C540F | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGEF3 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARSF | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- C4orf54 | c.2914T>A p.W972R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- C7 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- CACNA1D | c.2846C>T p.A949V (on ENST00000350061 / NM_001128840.3; = p.A969V on NM_000720.4) | Missense Mutation (SNP) | VAF 44/598 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- EIF2AK2 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EXPH5 | c.4091G>T p.R1364I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- FAM169A | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 50/600 reads (8%) | called by muse, mutect2
- FAM98A | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FIZ1 | c.1334T>G p.L445R | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- GFPT2 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 22/551 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.057); called by muse, mutect2
- HAPLN3 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- HSPA5 | c.459del p.M153Ifs*41 | Frame Shift Del (DEL) | VAF 24/201 reads (12%) | called by mutect2, pindel, varscan2
- KRTAP5-10 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 46/333 reads (14%) | PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MYO3B | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- NONO | c.47_50del p.P16Qfs*39 | Frame Shift Del (DEL) | VAF 49/392 reads (13%) | called by mutect2, pindel, varscan2
- PRDM9 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 226/1087 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- RAD17 | c.1935G>C p.L645F (on ENST00000380774 / NM_133339.2; = p.L634F on NM_002873.1) | Missense Mutation (SNP) | VAF 84/772 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RPS6KC1 | c.2315A>T p.D772V | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC31A | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- SHPRH | c.2117G>T p.C706F | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A1 | c.736A>G p.R246G | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31D1 | c.2492C>A p.T831K | Missense Mutation (SNP) | VAF 42/698 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- TRPA1 | c.662-2A>C p.X221_splice | Splice Site (SNP) | VAF 25/429 reads (6%) | called by muse, mutect2
- TSC22D2 | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZFPM2 | c.3437C>A p.A1146E | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZMAT1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2
- ZNF449 | c.300A>T p.R100S | Missense Mutation (SNP) | VAF 63/738 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF497 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ABRAXAS1 | c.669A>G p.Q223= | Silent (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
- ADAL | c.297C>T p.V99= | Silent (SNP) | VAF 38/496 reads (8%) | called by muse, mutect2
- ATP8B1 | c.2703C>T p.I901= | Silent (SNP) | VAF 15/411 reads (4%) | called by muse, mutect2
- BGN | c.144C>T p.G48= | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as rs371932706, COSV100525275; called by muse, mutect2
- BSND | c.702G>A p.P234= | Silent (SNP) | VAF 51/523 reads (10%) | catalogued as rs148085906; called by muse, mutect2, varscan2
- FAM162B | c.274C>A p.R92= | Silent (SNP) | VAF 19/310 reads (6%) | called by muse, mutect2
- H4C5 | c.198G>A p.V66= | Silent (SNP) | VAF 26/392 reads (7%) | catalogued as COSV63486077, COSV63486239; called by muse, mutect2
- HGSNAT | c.1398G>A p.V466= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as rs1277046882; called by muse, mutect2
- MS4A14 | c.1965A>G p.Q655= | Silent (SNP) | VAF 28/316 reads (9%) | called by muse, mutect2
- NUTM1 | c.2871A>C p.T957= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- OR2L2 | c.561C>A p.A187= | Silent (SNP) | VAF 77/314 reads (25%) | called by muse, mutect2, varscan2
- OR5AU1 | c.93C>T p.F31= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as rs1188712144; called by muse, mutect2
- OR5M10 | c.894C>T p.I298= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- PTPRU | c.3063C>T p.T1021= | Silent (SNP) | VAF 11/147 reads (7%) | called by muse, mutect2
- RADX | c.1164G>A p.Q388= | Silent (SNP) | VAF 30/410 reads (7%) | called by muse, mutect2
- RIOX1 | c.606G>T p.A202= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- STARD9 | c.10012C>T p.L3338= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as rs1049868847; called by muse, mutect2
- ZZEF1 | c.5829C>T p.V1943= | Silent (SNP) | VAF 70/608 reads (12%) | catalogued as rs553800356; called by muse, mutect2, varscan2
- ASH1L | c.7905+215T>A | Intron (SNP) | VAF 16/389 reads (4%) | called by muse, mutect2
- BAGE2 | n.123C>A | RNA (SNP) | VAF 19/496 reads (4%) | called by muse, mutect2
- CDH2 | c.*2C>T | 3'UTR (SNP) | VAF 40/450 reads (9%) | called by muse, mutect2
- FNBP1 | c.1171-9T>G | Intron (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- HMG20B | c.147+134C>T | Intron (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- HMGA1 | c.-35C>A | 5'UTR (SNP) | VAF 90/368 reads (24%) | called by muse, mutect2, varscan2
- LAPTM5 | c.*226C>T | 3'UTR (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- MLST8 | c.862+52G>A | Intron (SNP) | VAF 13/127 reads (10%) | catalogued as rs745714425; called by muse, mutect2, varscan2
- NCKAP5L | c.3792+106A>G | Intron (SNP) | VAF 22/309 reads (7%) | called by muse, mutect2
- NEB | c.11602-3108C>A | Intron (SNP) | VAF 49/616 reads (8%) | called by muse, mutect2, varscan2
- NIPAL4 | c.223+174C>T | Intron (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- ZFPM2 | c.740-2893C>G | Intron (SNP) | VAF 23/210 reads (11%) | catalogued as rs1005484813; called by muse, mutect2, varscan2
